Somatic mutation profile of tumor specimen C3L-01469-01 (aliquot CPT0389960006) from CPTAC case C3L-01469, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.7 years (21,798 days).
Specimen C3L-01469-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0214adf2-d1fd-4be6-889a-def8739594ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01469-31 (Blood Derived Normal), aliquot CPT0390020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87f8c0bd-47e0-4087-af42-739995a19f00

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Frame Shift Del 2, Splice Site 2, Silent 2, Nonsense Mutation 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIP2C | c.3958G>A p.V1320M | Missense Mutation (SNP) | VAF 84/131 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs759695360, COSV55153907; called by muse, mutect2, varscan2
- GREB1 | c.5074G>A p.A1692T | Missense Mutation (SNP) | VAF 256/364 reads (70%) | SIFT tolerated (0.05); PolyPhen benign (0.349); catalogued as rs991868518, COSV52195051; called by muse, mutect2, varscan2
- DNAH8 | c.5082+2T>C p.X1694_splice | Splice Site (SNP) | VAF 66/139 reads (47%) | called by muse, mutect2, varscan2
- FN1 | c.108G>T p.M36I | Missense Mutation (SNP) | VAF 162/227 reads (71%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRID2IP | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 138/347 reads (40%) | called by muse, mutect2, varscan2
- LAMA5 | c.2218G>T p.A740S | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT tolerated (0.41); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MTA2 | c.593+1del p.X198_splice | Splice Site (DEL) | VAF 56/146 reads (38%) | called by mutect2, pindel, varscan2
- PIK3C2A | c.4945G>T p.A1649S | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMC4 | c.2009del p.G670Vfs*2 | Frame Shift Del (DEL) | VAF 25/72 reads (35%) | called by mutect2, pindel
- TP53 | c.928_944del p.N310Sfs*21 | Frame Shift Del (DEL) | VAF 86/142 reads (61%) | called by mutect2, pindel, varscan2
- WDR3 | c.2723A>T p.E908V | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- DGKB | c.735C>T p.H245= | Silent (SNP) | VAF 52/154 reads (34%) | catalogued as rs1412650214; called by muse, mutect2, varscan2
- OR10S1 | c.294G>C p.L98= | Silent (SNP) | VAF 98/292 reads (34%) | catalogued as rs770960376; called by muse, mutect2
- AP000769.5 | chr11:65499134 del AT | 5'Flank (DEL) | VAF 59/178 reads (33%) | catalogued as rs1491393910; called by mutect2, pindel, varscan2
- PKD1 | c.11156+25_11156+26insTT | Intron (INS) | VAF 166/488 reads (34%) | called by mutect2, pindel, varscan2
